Somatic mutation profile of tumor specimen 0DN3SS from CCDI case PBCAZG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,137 days).
Specimen 0DN3SS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e047e96f-4d94-4d64-8aab-979c40347a71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN3R4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5c7f9bd-c047-4c56-96e1-d8f950c17ae7

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL2RA | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 173/822 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as rs1438968487, COSV56922108; called by muse, mutect2, varscan2
- KLHL22 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 29/459 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.353); called by muse, mutect2
- MAP3K4 | c.4445T>C p.F1482S | Missense Mutation (SNP) | VAF 174/1934 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AC073648.1 | n.136G>A | RNA (SNP) | VAF 12/81 reads (15%) | catalogued as rs757319952; called by mutect2, varscan2
- LETMD1 | c.915+61G>A | Intron (SNP) | VAF 16/423 reads (4%) | called by muse, mutect2
- NRP2 | c.251+48C>T | Intron (SNP) | VAF 60/521 reads (12%) | catalogued as rs374381885; called by muse, mutect2, varscan2
